Somatic mutation profile of tumor specimen TCGA-DD-AAE9-01A (aliquot TCGA-DD-AAE9-01A-11D-A40R-10) from TCGA case TCGA-DD-AAE9, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 69.7 years (25,451 days).
Specimen TCGA-DD-AAE9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) deb86530-5d34-4667-87ae-0339a0e1b1c8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AAE9-10A (Blood Derived Normal), aliquot TCGA-DD-AAE9-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c0c04607-5543-48f6-b815-1adb1c23525f

The open-access MAF lists 116 somatic variants for this specimen: 88 protein-altering or splice-affecting, 23 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 79, Silent 23, Frame Shift Del 3, Intron 3, Nonsense Mutation 3, Frame Shift Ins 2, Splice Site 1, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.121A>G p.T41A | Missense Mutation (SNP) | VAF 87/146 reads (60%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs121913412, COSV62687862, COSV62689580, COSV62714770; ClinVar: conflicting interpretations of pathogenicity / pathogenic /  other / likely pathogenic; called by muse, mutect2, varscan2
- ABCA1 | c.4228A>G p.K1410E | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV101036564; called by muse, mutect2, varscan2
- ABCA13 | c.11161C>A p.Q3721K | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1054156439, COSV101446780; called by muse, mutect2, varscan2
- ADAM12 | c.1558T>C p.Y520H | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV100900041; called by muse, mutect2, varscan2
- AIFM1 | c.1534A>G p.T512A | Missense Mutation (SNP) | VAF 91/108 reads (84%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs369259253, COSV99780764; called by muse, mutect2, varscan2
- ALLC | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as COSV99377484; called by muse, mutect2, varscan2
- AMDHD1 | c.1073C>G p.S358C | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99900202; called by muse, mutect2, varscan2
- ANG | c.323A>T p.H108L | Missense Mutation (SNP) | VAF 51/194 reads (26%) | SIFT tolerated (0.55); PolyPhen benign (0.012); catalogued as COSV100390832; called by muse, mutect2, varscan2
- ARHGEF10L | c.2401G>T p.A801S | Missense Mutation (SNP) | VAF 23/32 reads (72%) | SIFT tolerated (0.07); PolyPhen benign (0.087); catalogued as COSV99392007; called by muse, mutect2, varscan2
- ARHGEF12 | c.3795A>T p.Q1265H | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV100754665; called by muse, mutect2, varscan2
- BTN3A1 | c.1108G>T p.D370Y | Missense Mutation (SNP) | VAF 51/275 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.596); catalogued as COSV99175630; called by muse, mutect2, varscan2
- C9orf64 | c.653G>A p.S218N | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.723); catalogued as COSV100123491; called by muse, mutect2, varscan2
- CCHCR1 | c.335G>T p.R112L | Missense Mutation (SNP) | VAF 70/93 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV66161201, COSV66161514; called by muse, mutect2, varscan2
- CCN5 | c.352A>T p.S118C | Missense Mutation (SNP) | VAF 37/146 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV99509169; called by muse, mutect2, varscan2
- CNN1 | c.719C>T p.T240M | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs758562938, COSV99370587; called by muse, mutect2, varscan2
- CNTN2 | c.3077C>T p.S1026F | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); catalogued as COSV100084689; called by muse, mutect2
- CTSE | c.298T>C p.S100P | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.156); catalogued as COSV63061441; called by muse, mutect2, varscan2
- DAAM2 | c.1891G>C p.V631L | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.713); catalogued as COSV99224659; called by muse, mutect2, varscan2
- DLK2 | c.422C>T p.P141L | Missense Mutation (SNP) | VAF 52/176 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99766734; called by muse, mutect2, varscan2
- DNAH5 | c.13806T>A p.D4602E | Missense Mutation (SNP) | VAF 46/118 reads (39%) | SIFT tolerated (0.37); PolyPhen benign (0.009); catalogued as COSV99445301; called by muse, mutect2, varscan2
- DOP1B | c.3452G>A p.G1151E | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.245); catalogued as rs761015908, COSV101215067; called by muse, mutect2, varscan2
- ECPAS | c.1148T>C p.I383T | Missense Mutation (SNP) | VAF 48/161 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99397557; called by muse, mutect2, varscan2
- EOMES | c.605C>A p.P202Q | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.146); catalogued as COSV99841712; called by muse, mutect2, varscan2
- EPS8L1 | c.446A>T p.E149V (on ENST00000201647 / NM_133180.3; = p.E22V on NM_017729.3) | Missense Mutation (SNP) | VAF 67/150 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as COSV99135663; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1661A>T p.K554I | Missense Mutation (SNP) | VAF 87/271 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as COSV100435656; called by muse, mutect2, varscan2
- GRIK1 | c.343T>A p.S115T | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT tolerated (0.47); PolyPhen benign (0.287); catalogued as COSV100515907; called by muse, mutect2, varscan2
- GRIP1 | c.3259C>A p.L1087M (on ENST00000359742 / NM_001379345.1; = p.L1035M on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 75/174 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.736); catalogued as COSV99668090; called by muse, mutect2, varscan2
- HCAR2 | c.484C>A p.L162I | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.919); catalogued as COSV100186418; called by muse, mutect2, varscan2
- HCRTR2 | c.1050C>G p.H350Q | Missense Mutation (SNP) | VAF 40/171 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100904171; called by muse, mutect2, varscan2
- HDX | c.1814T>G p.L605W | Missense Mutation (SNP) | VAF 207/254 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99946625; called by muse, mutect2, varscan2
- HLA-A | c.128A>T p.E43V | Missense Mutation (SNP) | VAF 64/181 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV100954294; called by muse, mutect2, varscan2
- HSPG2 | c.11248A>G p.T3750A | Missense Mutation (SNP) | VAF 163/213 reads (77%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as COSV101013334; called by muse, mutect2, varscan2
- LHFPL5 | c.128T>A p.L43H | Missense Mutation (SNP) | VAF 51/137 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV100798928; called by muse, mutect2, varscan2
- LOXL4 | c.1658T>A p.L553H | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99583593; called by muse, mutect2, varscan2
- MEI1 | c.442A>T p.M148L | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as COSV100299609; called by muse, mutect2
- MRC2 | c.454C>T p.Q152* | Nonsense Mutation (SNP) | VAF 21/57 reads (37%) | catalogued as COSV100315830; called by muse, mutect2, varscan2
- MRPL1 | c.683G>T p.R228L | Missense Mutation (SNP) | VAF 155/422 reads (37%) | SIFT tolerated (0.65); PolyPhen benign (0.014); catalogued as COSV100213762; called by muse, mutect2, varscan2
- MRPS9 | c.465A>T p.K155N | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99305874; called by muse, mutect2, varscan2
- N4BP2 | c.2783A>T p.E928V | Missense Mutation (SNP) | VAF 69/178 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.444); catalogued as COSV99788215; called by muse, mutect2, varscan2
- NF1 | c.4401T>A p.F1467L (on ENST00000358273 / NM_001042492.3; = p.F1446L on NM_000267.3) | Missense Mutation (SNP) | VAF 5/116 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.134); catalogued as COSV100646052; called by muse, mutect2
- NMUR1 | c.13T>G p.C5G | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV100531807; called by mutect2, varscan2
- NPSR1 | c.568C>G p.L190V | Missense Mutation (SNP) | VAF 55/100 reads (55%) | SIFT tolerated (0.27); PolyPhen benign (0.326); catalogued as COSV100705755; called by muse, mutect2, varscan2
- OGA | c.1939A>T p.I647F | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); catalogued as COSV100761660; called by muse, mutect2, varscan2
- OR1L4 | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs370090548; called by muse, mutect2, varscan2
- OSBPL1A | c.136A>G p.N46D | Missense Mutation (SNP) | VAF 144/406 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100111140; called by muse, mutect2, varscan2
- OTOGL | c.3472A>G p.K1158E (on ENST00000547103; = p.K1149E on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.717); catalogued as COSV101509025; called by muse, mutect2, varscan2
- OTULIN | c.538A>G p.K180E | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as rs746061545, COSV99419561; called by muse, mutect2, varscan2
- P4HA1 | c.899T>C p.M300T | Missense Mutation (SNP) | VAF 56/95 reads (59%) | SIFT deleterious (0.02); PolyPhen benign (0.322); catalogued as COSV99696563; called by muse, mutect2, varscan2
- PCSK9 | c.1682-1G>T p.X561_splice | Splice Site (SNP) | VAF 93/186 reads (50%) | catalogued as COSV99598899; called by muse, mutect2, varscan2
- PRKDC | c.2222T>C p.I741T | Missense Mutation (SNP) | VAF 69/294 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as rs1456557309, COSV100038511; called by muse, mutect2, varscan2
- PRMT2 | c.175A>T p.I59F | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.178); catalogued as COSV99388460; called by muse, mutect2, varscan2
- PRSS21 | c.99C>A p.C33* | Nonsense Mutation (SNP) | VAF 7/56 reads (13%) | catalogued as rs1212714453, COSV99135463; called by muse, mutect2, varscan2
- PSG8 | c.320T>C p.L107P | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100125992, COSV100126032; called by muse, mutect2, varscan2
- PTPN21 | c.1936G>T p.G646C | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.832); catalogued as rs576261282, COSV100161511; called by muse, mutect2, varscan2
- RAB30 | c.436A>G p.M146V | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.443); catalogued as rs754885957, COSV99475543; called by muse, mutect2, varscan2
- RAPGEF6 | c.182A>G p.N61S | Missense Mutation (SNP) | VAF 105/358 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV99725321; called by muse, mutect2, varscan2
- RBFOX1 | c.959A>T p.Q320L | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1338713162, COSV100299694; called by muse, mutect2, varscan2
- RPGRIP1 | c.1632G>A p.M544I | Missense Mutation (SNP) | VAF 45/153 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs1273869576, COSV99250482; called by muse, mutect2, varscan2
- RPGRIP1 | c.1633A>T p.T545S | Missense Mutation (SNP) | VAF 43/150 reads (29%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.87); catalogued as rs756799100, COSV99250485; called by muse, mutect2, varscan2
- RTKN2 | c.1411G>C p.A471P | Missense Mutation (SNP) | VAF 55/101 reads (54%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.95); catalogued as COSV100189212; called by muse, mutect2, varscan2
- RYR1 | c.12647T>A p.F4216Y | Missense Mutation (SNP) | VAF 261/656 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as COSV100614535; called by muse, mutect2, varscan2
- SCEL | c.1945A>T p.K649* (on ENST00000349847 / NM_144777.3; = p.K629* on NM_003843.4) | Nonsense Mutation (SNP) | VAF 33/97 reads (34%) | catalogued as COSV100582604; called by muse, mutect2, varscan2
- SENP7 | c.2273G>T p.G758V | Missense Mutation (SNP) | VAF 143/536 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100052482, COSV58611292; called by muse, mutect2, varscan2
- SLC22A9 | c.1501A>G p.I501V | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0.161); catalogued as COSV99654739; called by muse, mutect2, varscan2
- SLC2A6 | c.1479G>C p.Q493H | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99390093; called by muse, mutect2, varscan2
- SLC43A1 | c.1583C>T p.S528F | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV99560751; called by muse, mutect2, varscan2
- SLIT3 | c.193C>A p.R65S | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100265497; called by muse, mutect2, varscan2
- STXBP6 | c.446T>C p.M149T | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV100121532; called by muse, mutect2, varscan2
- SYT1 | c.978G>T p.K326N | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54069149; called by muse, mutect2, varscan2
- TAMALIN | c.159C>A p.D53E | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV99531007; called by muse, mutect2, varscan2
- TBC1D2B | c.2228C>A p.S743Y | Missense Mutation (SNP) | VAF 73/91 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100316840, COSV56038627; called by muse, mutect2, varscan2
- TOP1MT | c.110G>A p.G37D | Missense Mutation (SNP) | VAF 79/237 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.026); catalogued as COSV100239213; called by muse, mutect2, varscan2
- TPD52 | c.547A>T p.N183Y (on ENST00000379097 / NM_001025252.3; = p.N143Y on NM_005079.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV100990706; called by muse, mutect2, varscan2
- TRPM8 | c.1314G>T p.Q438H | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100223632, COSV61223691; called by muse, mutect2, varscan2
- TTC8 | c.1035C>G p.I345M (on ENST00000338104 / NM_001288781.1; = p.I329M on NM_144596.4) | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.418); catalogued as COSV100581046, COSV100581294; called by muse, mutect2, varscan2
- UGT2B10 | c.1419A>T p.K473N | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99607881; called by muse, mutect2, varscan2
- UTP25 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 98/203 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.1); catalogued as COSV101504723; called by muse, mutect2, varscan2
- VEGFC | c.341A>T p.Y114F | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV99709474; called by muse, mutect2, varscan2
- WDR26 | c.2087A>C p.Y696S (on ENST00000414423 / NM_001379403.1; = p.Y596S on NM_025160.7) | Missense Mutation (SNP) | VAF 78/191 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99690875; called by muse, mutect2, varscan2
- WT1 | c.22G>A p.D8N | Missense Mutation (SNP) | VAF 46/134 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV60065879; called by muse, mutect2, varscan2
- YBX2 | c.530G>A p.R177Q | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs1208409184, COSV99142645; called by muse, mutect2, varscan2
- ZFYVE26 | c.2576A>T p.K859M | Missense Mutation (SNP) | VAF 50/113 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.885); catalogued as COSV100720096; called by muse, mutect2, varscan2
- ZNF804A | c.2816G>A p.R939K | Missense Mutation (SNP) | VAF 47/117 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV56451294; called by muse, mutect2, varscan2
- APOB | c.4919dup p.H1641Sfs*23 | Frame Shift Ins (INS) | VAF 22/63 reads (35%) | called by mutect2, pindel, varscan2
- DNM1L | c.1088_1109del p.G363Afs*9 | Frame Shift Del (DEL) | VAF 25/100 reads (25%) | called by mutect2, pindel, varscan2
- FAM71C | c.626del p.M209Rfs*17 | Frame Shift Del (DEL) | VAF 15/65 reads (23%) | called by mutect2, pindel, varscan2
- FREM2 | c.3540dup p.I1181Hfs*8 | Frame Shift Ins (INS) | VAF 37/106 reads (35%) | called by mutect2, pindel, varscan2
- TMEM81 | c.528del p.F176Lfs*3 | Frame Shift Del (DEL) | VAF 95/273 reads (35%) | called by mutect2, pindel, varscan2
- ABCD1 | c.1530C>G p.G510= | Silent (SNP) | VAF 37/78 reads (47%) | catalogued as COSV99497259, COSV99497345; called by muse, mutect2, varscan2
- ABCD2 | c.511T>C p.L171= | Silent (SNP) | VAF 92/212 reads (43%) | catalogued as COSV100429163; called by muse, mutect2, varscan2
- CAT | c.966A>G p.P322= | Silent (SNP) | VAF 45/113 reads (40%) | catalogued as COSV99573105; called by muse, mutect2, varscan2
- CLEC6A | c.213A>G p.T71= | Silent (SNP) | VAF 17/60 reads (28%) | catalogued as COSV101165615; called by muse, mutect2, varscan2
- EHD2 | c.477G>A p.S159= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as rs369297316, COSV99621643; called by muse, mutect2, varscan2
- G6PC | c.888C>G p.L296= | Silent (SNP) | VAF 29/100 reads (29%) | catalogued as rs1266860369, COSV99520648; ClinVar: likely benign; called by muse, mutect2, varscan2
- GDI2 | c.315T>A p.T105= | Silent (SNP) | VAF 78/158 reads (49%) | catalogued as COSV101200708, COSV101200732; called by muse, mutect2, varscan2
- GPR55 | c.171T>A p.A57= | Silent (SNP) | VAF 59/163 reads (36%) | catalogued as COSV101235711; called by muse, mutect2, varscan2
- HDAC7 | c.2541C>A p.A847= (on ENST00000427332; = p.A886= on NM_015401.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 52/127 reads (41%) | catalogued as COSV99315581; called by muse, mutect2, varscan2
- HDX | c.1815G>A p.L605= | Silent (SNP) | VAF 204/253 reads (81%) | catalogued as COSV99946623; called by muse, mutect2, varscan2
- HK3 | c.234C>T p.Y78= | Silent (SNP) | VAF 16/32 reads (50%) | catalogued as rs769304037, COSV99457707; called by muse, mutect2, varscan2
- INTS3 | c.2517C>T p.A839= | Silent (SNP) | VAF 25/66 reads (38%) | catalogued as COSV99669710; called by muse, mutect2, varscan2
- LRRC71 | c.1029G>C p.T343= | Silent (SNP) | VAF 19/152 reads (13%) | catalogued as COSV100503812; called by muse, mutect2, varscan2
- PCDHB1 | c.1923G>A p.L641= | Silent (SNP) | VAF 34/87 reads (39%) | catalogued as COSV100128027; called by muse, mutect2, varscan2
- POLD1 | c.75T>C p.D25= | Silent (SNP) | VAF 20/74 reads (27%) | catalogued as rs1015663503, COSV101486762; ClinVar: likely benign; called by muse, mutect2, varscan2
- SFMBT2 | c.1965T>C p.I655= | Silent (SNP) | VAF 48/88 reads (55%) | catalogued as COSV100738423; called by muse, mutect2, varscan2
- SLC25A25 | c.612G>T p.T204= | Silent (SNP) | VAF 22/57 reads (39%) | catalogued as COSV100895253; called by muse, mutect2, varscan2
- TEP1 | c.5196C>G p.L1732= | Silent (SNP) | VAF 47/181 reads (26%) | catalogued as rs764524084, COSV99401680; called by muse, mutect2, varscan2
- TEX15 | c.447T>C p.C149= (on ENST00000256246; = p.C532= on NM_001350162.2) | Silent (SNP) | VAF 28/53 reads (53%) | catalogued as COSV56354908, COSV99820733; called by muse, mutect2, varscan2
- TNS3 | c.885A>G p.E295= | Silent (SNP) | VAF 52/202 reads (26%) | catalogued as rs1007515217, COSV100234784; called by muse, mutect2, varscan2
- WASF3 | c.738G>A p.T246= | Silent (SNP) | VAF 57/147 reads (39%) | catalogued as rs757584113, COSV58964480; called by muse, mutect2, varscan2
- ZBTB4 | c.1797T>G p.P599= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as COSV100262754; called by muse, mutect2, varscan2
- ZNF45 | c.489C>T p.P163= | Silent (SNP) | VAF 26/73 reads (36%) | catalogued as COSV99524005; called by muse, mutect2, varscan2
- CBARP | c.1214+67T>C | Intron (SNP) | VAF 26/56 reads (46%) | catalogued as rs1568731101, COSV99289344; called by muse, varscan2
- GRID1 | c.236-58067T>A | Intron (SNP) | VAF 28/71 reads (39%) | catalogued as COSV100022011; called by muse, mutect2, varscan2
- MIR1251 | n.23G>A | RNA (SNP) | VAF 20/53 reads (38%) | catalogued as rs780390275; called by muse, mutect2, varscan2
- NCF4 | c.759-93C>T | Intron (SNP) | VAF 34/107 reads (32%) | catalogued as COSV99957095; called by muse, mutect2, varscan2
- POLR1C | chr6:43513113 G>A | 5'Flank (SNP) | VAF 32/147 reads (22%) | catalogued as rs761449765, COSV100396706; called by muse, mutect2, varscan2
